Gene-level copy-number profile of tumor specimen TCGA-02-0290-01A from TCGA case TCGA-02-0290, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.5 years (18,066 days).
Specimen TCGA-02-0290-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.0385c3f0-7906-4e91-b2bb-aa95239eac1c.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,081 have no estimate.
https://portal.gdc.cancer.gov/files/977493e2-75f6-4c3e-a9a1-336d80bd377f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 169; copy number 1: 2,830; copy number 2: 45,962; copy number 3: 6,440; copy number 4: 118; copy number 7: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0290-01): tumor purity 0.75, ploidy 2.03, whole-genome doublings 0 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 169 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,954,291–9,729,114, 53 genes: PARK7, Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA, RERE, RERE-AS1, AL096855.1, AL096855.2, RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5, AL158048.1, GPR157, MIR34AHG, MIR34A, LNCTAM34A, H6PD, SPSB1, BX323043.1, LINC02606, RNA5SP40, AL928921.1, SLC25A33, AL954705.1, TMEM201, PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2.
- chr9:20,658,309–28,888,955, 116 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:53,701,692–55,049,318, 23 genes, copy number 7: FTO, AC007496.2, AC007496.3, AC007496.1, AC007347.1, AC007347.2, AC007907.1, LINC02169, IRX3, AC018553.2, AC018553.1, LINC02140, AC018553.3, AC007343.1, LINC02183, AC007491.1, CRNDE, AC106742.1, IRX5, AC106738.1, AC106738.2, MTND5P34, AC109136.1.

Autosomal genes at a single copy (total copy number 1): 2,830. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
